Somatic mutation profile of tumor specimen TCGA-CQ-5327-01A (aliquot TCGA-CQ-5327-01A-01D-1683-08) from TCGA case TCGA-CQ-5327, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.1 years (22,307 days).
Specimen TCGA-CQ-5327-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00090260-4b82-4f75-a257-1d42cf25572c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5327-10A (Blood Derived Normal), aliquot TCGA-CQ-5327-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb09231a-8b02-4edb-a92a-d06f2dd54267

The open-access MAF lists 252 somatic variants for this specimen: 187 protein-altering or splice-affecting, 56 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 56, Nonsense Mutation 12, Frame Shift Del 5, Frame Shift Ins 5, Intron 4, Splice Region 3, Splice Site 3, RNA 3, In Frame Del 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, varscan2
- MSH3 | c.1148dup p.N385Qfs*19 | Frame Shift Ins (INS) | VAF 33/133 reads (25%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA13 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573740053, COSV101329921, COSV70026109; called by muse, mutect2, varscan2
- ABCA13 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV101330161; called by muse, mutect2, varscan2
- ABCF3 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as COSV53053385, COSV99491452; called by muse, mutect2, varscan2
- ABL2 | c.1522G>A p.E508K (on ENST00000502732 / NM_007314.4; = p.E493K on NM_005158.5) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV100772941; called by muse, mutect2, varscan2
- ADAMDEC1 | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56475479, COSV99836291; called by muse, mutect2, varscan2
- ADAMTS3 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs998578473, COSV99711930; called by muse, mutect2, varscan2
- ADAMTS9 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1046694133, COSV99900100; called by muse, mutect2, varscan2
- ADGRV1 | c.14884T>C p.W4962R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101316427; called by muse, varscan2
- ADPGK | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142833607, COSV100295362; called by muse, mutect2, varscan2
- AGPAT4 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV100211962; called by muse, mutect2, varscan2
- AHNAK | c.12659C>G p.S4220* | Nonsense Mutation (SNP) | VAF 76/342 reads (22%) | catalogued as COSV99949366; called by muse, mutect2, varscan2
- AJUBA | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV52985018; called by muse, mutect2, varscan2
- ARMC8 | c.301C>G p.L101V (on ENST00000469044 / NM_001363941.2; = p.L87V on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100627850; called by muse, mutect2, varscan2
- ATP8A2 | c.3166C>G p.P1056A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.997); catalogued as COSV99683982; called by muse, mutect2, varscan2
- BANK1 | c.132G>C p.L44F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536767; called by muse, mutect2
- BHLHE40 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs141865687; called by muse, mutect2, varscan2
- BTAF1 | c.1146G>C p.M382I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs1452127719, COSV99795747; called by muse, mutect2, varscan2
- BTN3A3 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as COSV99765028; called by muse, mutect2, varscan2
- C10orf120 | c.704dup p.N235Kfs*28 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | catalogued as rs775451807; called by mutect2, pindel
- CA4 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.715); catalogued as rs752951171, COSV56281298; called by muse, mutect2, varscan2
- CACNA1D | c.5606G>A p.S1869N (on ENST00000350061 / NM_001128840.3; = p.S1889N on NM_000720.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1266126300; called by muse, mutect2, varscan2
- CCDC51 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491970, COSV56494760, COSV99603362; called by muse, mutect2, varscan2
- CCDC88A | c.2555T>A p.L852* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99711112; called by muse, mutect2, varscan2
- CCNE2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100353859; called by muse, mutect2, varscan2
- CCP110 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101195334; called by muse, mutect2, varscan2
- CD163 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765869382, COSV63136320; called by muse, mutect2, varscan2
- CDH19 | c.1577-1G>C p.X526_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100052222; called by muse, mutect2, varscan2
- CDKN2AIP | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs747629501, COSV100187718; called by muse, mutect2, varscan2
- CDON | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375179830; called by muse, mutect2, varscan2
- CFTR | c.1621C>A p.L541I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.608); catalogued as COSV50073317; called by muse, mutect2, varscan2
- CKB | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV100818955; called by muse, mutect2, varscan2
- CLOCK | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100011980; called by muse, mutect2
- COL14A1 | c.5185C>T p.P1729S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52859787; called by muse, mutect2, varscan2
- COL17A1 | c.3371C>G p.S1124C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100793337; called by muse, mutect2, varscan2
- COX19 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774371118, COSV100700440; called by muse, mutect2, varscan2
- CPB1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs778982431, COSV51575049; called by muse, mutect2, varscan2
- CSMD2 | c.7243G>C p.D2415H | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99594671; called by muse, mutect2, varscan2
- CTCF | c.1612C>G p.L538V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99866502; called by muse, varscan2
- CTCF | c.1673C>G p.S558C | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99866504; called by muse, varscan2
- CTNNA1 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs1294176302, COSV57069858; called by muse, mutect2, varscan2
- CYLC1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100255363; called by muse, mutect2
- CYP4B1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs753414725, COSV99597437; called by muse, mutect2, varscan2
- DGAT2 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99929972; called by muse, mutect2, varscan2
- DOCK2 | c.4786C>T p.R1596* | Nonsense Mutation (SNP) | VAF 37/128 reads (29%) | catalogued as COSV56951180, COSV99914045; called by muse, mutect2, varscan2
- EBNA1BP2 | c.873G>A p.K291= | Splice Region (SNP) | VAF 13/88 reads (15%) | catalogued as COSV52539492, COSV99356089; called by muse, mutect2, varscan2
- EFCAB6 | c.4463C>G p.S1488* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as COSV99414300; called by muse, mutect2
- EFNB1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs778669520, COSV99214967; called by muse, varscan2
- EMX2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as rs1426142917, COSV71294387, COSV71294478; called by muse, mutect2, varscan2
- EP300 | c.2893C>T p.Q965* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99608898, COSV99609652; called by muse, mutect2, varscan2
- EPM2AIP1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99212667; called by muse, mutect2, varscan2
- ERBIN | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99397714; called by muse, varscan2
- FAM153B | c.373G>A p.E125K (on ENST00000253490; = p.E48K on NM_001265615.1) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.81); catalogued as rs1283388844, COSV99499128; called by muse, mutect2, varscan2
- FAT1 | c.6611T>G p.V2204G | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV101499620, COSV71673667; called by muse, varscan2
- FAT1 | c.6539C>T p.P2180L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101499621; called by muse, varscan2
- FAT2 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99943994; called by muse, mutect2, varscan2
- FAT2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV55827422; called by muse, mutect2, varscan2
- FBLN2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs551629994, COSV99851586; called by muse, mutect2, varscan2
- FBXO41 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV99721530; called by muse, mutect2, varscan2
- FERMT3 | c.1801A>T p.N601Y (on ENST00000279227 / NM_178443.3; = p.N597Y on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99656027; called by muse, mutect2, varscan2
- FPR2 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100389428; called by muse, mutect2, varscan2
- FUT2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs201026795, COSV101218146; called by muse, mutect2, varscan2
- FZD8 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV65967681; called by muse, mutect2, varscan2
- GHR | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100051898; called by muse, mutect2, varscan2
- GPC5 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs559277707, COSV65579895; called by muse, mutect2, varscan2
- GRK3 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.849); catalogued as COSV100151967; called by muse, mutect2, varscan2
- HECTD4 | c.2582C>G p.S861C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100296199; called by muse, mutect2, varscan2
- HIBCH | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV100676272; called by muse, mutect2, varscan2
- HTR1E | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143974435; called by muse, mutect2, varscan2
- IL10RA | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV99923240; called by muse, mutect2, varscan2
- IRF9 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as COSV100138265, COSV60704389; called by muse, mutect2, varscan2
- ITPR3 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV100968053; called by muse, mutect2
- KALRN | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99567033; called by muse, mutect2, varscan2
- KALRN | c.6315G>A p.M2105I (on ENST00000360013 / NM_001024660.4; = p.M408I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV52260754; called by muse, mutect2, varscan2
- KCNJ15 | c.310C>G p.H104D | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV100154376; called by muse, mutect2, varscan2
- KDM4B | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV99347337; called by muse, mutect2, varscan2
- KIF24 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100799315; called by muse, mutect2, varscan2
- KLHL41 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375214560; called by muse, mutect2, varscan2
- KPNA5 | c.1164G>C p.E388D | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100706400; called by muse, mutect2, varscan2
- KRT2 | c.1414G>C p.A472P | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100548632; called by muse, mutect2, varscan2
- KYNU | c.1342T>C p.Y448H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV99933944; called by muse, mutect2, varscan2
- LCT | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.067); catalogued as COSV99928191, COSV99930333; called by muse, mutect2, varscan2
- LGALS4 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs537002104, COSV100313358; called by muse, mutect2, varscan2
- LHFPL1 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100914513; called by muse, mutect2, varscan2
- LRPPRC | c.3365-1G>C p.X1122_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99581387; called by muse, mutect2, varscan2
- LRRC1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as COSV100906544; called by muse, mutect2, varscan2
- MAGEA10 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as COSV54886371, COSV99726896; called by muse, mutect2, varscan2
- MAPT | c.1135C>G p.H379D (on ENST00000262410 / NM_001377265.1; = p.H304D on NM_016835.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.925); catalogued as COSV99291158, COSV99291236; called by muse, mutect2, varscan2
- MBD6 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100851807; called by muse, mutect2, varscan2
- MC4R | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV55352152; called by muse, mutect2, varscan2
- MCMDC2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as rs751075073, COSV58041334; called by muse, mutect2, varscan2
- MINDY4 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99519197; called by muse, mutect2, varscan2
- MOS | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs1421842842, COSV61336285; called by muse, mutect2, varscan2
- MTOR | c.6267G>A p.M2089I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs542723817, COSV100816625; called by muse, mutect2, varscan2
- MUC16 | c.20498C>T p.S6833L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as COSV101201372; called by muse, mutect2, varscan2
- MYBPC1 | c.250G>A p.E84K (on ENST00000550270 / NM_206820.2; = p.E109K on NM_002465.4) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62253170; called by muse, mutect2, varscan2
- MYOM1 | c.2665C>G p.Q889E | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99868175; called by muse, mutect2, varscan2
- NCBP2 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV100052243; called by muse, mutect2, varscan2
- NCOA3 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773838233, COSV59067658; called by muse, mutect2, varscan2
- NCOA6 | c.4381G>A p.D1461N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.205); catalogued as rs1046370234, COSV100750309; called by muse, mutect2, varscan2
- NEIL3 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376062379; called by muse, mutect2, varscan2
- NKD1 | c.1088G>C p.R363T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99194116; called by muse, mutect2, varscan2
- NRCAM | c.175G>A p.D59N (on ENST00000379028 / NM_001371124.1; = p.D53N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100695387; called by muse, mutect2, varscan2
- NUP205 | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV99607518; called by muse, mutect2, varscan2
- OR2AT4 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.782); catalogued as COSV100532398, COSV59407278; called by muse, mutect2, varscan2
- OR4C11 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100155485; called by muse, mutect2, varscan2
- OR51M1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs775812594, COSV100150366; called by muse, mutect2, varscan2
- OR5R1 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100393349, COSV100393573, COSV56572646; called by muse, mutect2, varscan2
- OXSR1 | c.802A>C p.I268L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV100309613; called by muse, mutect2, varscan2
- PAK5 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as COSV62027600; called by muse, mutect2, varscan2
- PARP8 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV55864735; called by muse, mutect2, varscan2
- PC | c.2830G>A p.V944M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747039077, COSV58992372; called by muse, mutect2, varscan2
- PCDH10 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs1321093154, COSV52094407; called by muse, mutect2, varscan2
- PCDHA11 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs1235290760, COSV100253946; called by muse, mutect2, varscan2
- PCDHGA11 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV53906668; called by muse, mutect2
- PDE1C | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV58517800; called by muse, mutect2, varscan2
- PDE4D | c.991G>C p.E331Q (on ENST00000340635 / NM_001104631.2; = p.E195Q on NM_006203.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100402130; called by muse, mutect2, varscan2
- PDYN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370283678, COSV54101461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX1 | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137856931; called by muse, mutect2, varscan2
- PFKFB1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs368782445, COSV100895836; called by muse, mutect2, varscan2
- PHYH | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs538686726, COSV53815029, COSV53815190; called by muse, mutect2, varscan2
- PLCE1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as COSV99596911; called by muse, mutect2, varscan2
- PLEC | c.7051G>A p.A2351T (on ENST00000322810 / NM_201380.4; = p.A2241T on NM_000445.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.107); catalogued as rs1554691805, COSV100518417; called by muse, mutect2, varscan2
- POLQ | c.4527G>A p.M1509I | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99952870; called by muse, mutect2, varscan2
- POLQ | c.3782G>A p.R1261K | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.039); catalogued as COSV99952872; called by muse, mutect2, varscan2
- PPP1R11 | c.345C>G p.D115E | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99748679; called by muse, mutect2, varscan2
- PRICKLE2 | c.2676G>T p.Q892H (on ENST00000295902; = p.Q836H on NM_198859.4) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.894); catalogued as COSV99897972; called by muse, mutect2, varscan2
- PRRC2B | c.4078G>C p.E1360Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV100622178; called by muse, mutect2, varscan2
- PSG6 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99414476; called by muse, mutect2, varscan2
- PTPN14 | c.2535G>A p.M845I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1327503875, COSV100872912; called by muse, mutect2, varscan2
- PTPRM | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs150274533; called by muse, mutect2, varscan2
- PYGM | c.1095G>A p.A365= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as rs1370804680, COSV51215220, COSV99377566; ClinVar: likely benign; called by muse, mutect2
- RACGAP1 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV100407934; called by muse, mutect2, varscan2
- RAPGEF5 | c.982_984del p.E328del | In Frame Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs1256574068; called by mutect2, pindel, varscan2
- RELN | c.8269T>C p.F2757L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs560897786, COSV100634784; called by muse, mutect2, varscan2
- REV3L | c.7073-1G>C p.X2358_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100725650; called by muse, mutect2
- RINT1 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV99994569; called by muse, mutect2, varscan2
- RSAD2 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV65908805; called by muse, mutect2, varscan2
- SAMD1 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54116285; called by muse, mutect2, varscan2
- SCAF4 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99742082; called by muse, mutect2, varscan2
- SGO2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100764788; called by muse, mutect2, varscan2
- SH3BP4 | c.2878G>A p.D960N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.734); catalogued as rs200804299, COSV60643322; called by muse, mutect2
- SH3TC1 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs986368503, COSV55283847, COSV99795124; called by muse, mutect2, varscan2
- SHANK2 | c.4517C>T p.T1506M | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs146717159, CM103056; called by muse, mutect2, varscan2
- SHROOM1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs942000788, COSV100167245; called by muse, mutect2, varscan2
- SIGLEC6 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV100585657; called by muse, mutect2, varscan2
- SIN3B | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs761831913, COSV99932011; called by muse, mutect2, varscan2
- SLC4A10 | c.2947G>T p.V983L (on ENST00000446997 / NM_001354461.2; = p.V953L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99765545; called by muse, mutect2, varscan2
- SLC9A3 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99376589; called by muse, mutect2, varscan2
- SMG5 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100700905; called by muse, mutect2, varscan2
- SOX2 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV57621786; called by muse, mutect2, varscan2
- SPAG17 | c.3088C>G p.Q1030E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV100310371; called by muse, mutect2
- SRSF5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99384498; called by muse, mutect2, varscan2
- TACR3 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1008776547, CM103249, COSV59199133; called by muse, mutect2, varscan2
- TAGLN | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs1234635687, COSV99639201; called by muse, mutect2, varscan2
- TASOR2 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100050961; called by muse, mutect2, varscan2
- TBXT | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as COSV51617756; called by muse, mutect2
- TENM1 | c.4496C>G p.S1499C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100950568, COSV100950804; called by muse, mutect2, varscan2
- TICAM1 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99941261; called by muse, mutect2, varscan2
- TLNRD1 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99146151; called by muse, mutect2
- TMEM135 | c.399C>T p.A133= | Splice Region (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100450107; called by muse, mutect2, varscan2
- TMEM183A | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.723); catalogued as COSV100923711; called by muse, mutect2, varscan2
- TPM1 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV99147445; called by muse, mutect2, varscan2
- TRPA1 | c.3229G>C p.E1077Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100085085; called by muse, mutect2, varscan2
- TRPM3 | c.2541G>C p.K847N (on ENST00000357533 / NM_001366142.2; = p.K690N on NM_020952.6) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100678594; called by muse, mutect2, varscan2
- TTN | c.78659C>G p.S26220C (on ENST00000591111; = p.S18796C on NM_003319.4) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | PolyPhen probably damaging (0.987); catalogued as COSV100627541; called by muse, mutect2, varscan2
- TUBGCP6 | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs755654925, COSV99956231; called by muse, mutect2, varscan2
- USP15 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99740540; called by muse, mutect2, varscan2
- WDR64 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV63792682; called by muse, mutect2, varscan2
- WWC1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780398674, COSV99515809; called by muse, mutect2, varscan2
- ZAN | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.622); catalogued as COSV100770278; called by muse, mutect2, varscan2
- ZNF408 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100305659; called by muse, mutect2, varscan2
- ZNF496 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs781476350, COSV54176904, COSV54182903; called by muse, mutect2, varscan2
- ZNF526 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV55900906; called by muse, mutect2, varscan2
- ZNF568 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100451418, COSV99067993; called by muse, mutect2, varscan2
- ZNF804A | c.1229C>A p.T410N | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100171043, COSV56466840; called by muse, mutect2, varscan2
- ZSWIM4 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54319102; called by muse, mutect2
- ABCC10 | c.430del p.A144Lfs*4 (on ENST00000372530 / NM_001198934.2; = p.A101Lfs*4 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- ANXA2R | c.86_89dup p.E31Ffs*24 | Frame Shift Ins (INS) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- CASP8 | c.294_297del p.I98Mfs*14 (on ENST00000432109 / NM_033355.3; = p.I98Mfs*10 on NM_001228.4) | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel
- DLL1 | c.1798_1800del p.K600del | In Frame Del (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- EPHA2 | c.566_567del p.V189Gfs*24 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by pindel, varscan2
- IRF2BP2 | c.1103_1104dup p.P369Gfs*24 | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- PLA2R1 | c.2627dup p.L877Tfs*8 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- RB1 | c.157_160delinsAAA p.E53Kfs*12 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by pindel, varscan2*
- TECTA | c.265del p.L89* | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- ACLY | c.726C>T p.F242= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as rs782400219, COSV61249818; called by muse, mutect2
- ADGRF3 | c.3024C>G p.L1008= (on ENST00000311519 / NM_001145168.1; = p.L809= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100275394, COSV100275505; called by muse, mutect2
- ADGRF3 | c.2808C>T p.I936= (on ENST00000311519 / NM_001145168.1; = p.I737= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100275396; called by muse, mutect2, varscan2
- ADRM1 | c.963G>A p.P321= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs201200661, COSV99442013; called by muse, mutect2, varscan2
- AJUBA | c.93C>T p.P31= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1172862858, COSV99401168; called by muse, mutect2, varscan2
- ALG11 | c.27C>T p.C9= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs748982784, COSV99666913; called by muse, mutect2
- ARAP2 | c.804G>C p.V268= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs780823177, COSV100395183; called by muse, mutect2, varscan2
- ARSI | c.573C>T p.F191= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs150264448; called by muse, mutect2, varscan2
- CDK3 | c.249C>T p.L83= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV101159353; called by muse, mutect2, varscan2
- CES3 | c.1200G>T p.S400= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100310037; called by muse, mutect2, varscan2
- CHRD | c.915C>T p.L305= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99200738; called by muse, mutect2, varscan2
- CNTN1 | c.1830G>C p.L610= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as COSV100751637, COSV100751864; called by muse, mutect2, varscan2
- DNAH11 | c.6711C>G p.L2237= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100180590; called by mutect2, varscan2
- EDC4 | c.1269C>T p.L423= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as COSV62766781; called by muse, mutect2, varscan2
- ESPL1 | c.1347G>A p.L449= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99229723; called by muse, mutect2, varscan2
- GABRG1 | c.1200T>C p.D400= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99778652; called by muse, mutect2, varscan2
- GBP2 | c.1077G>A p.E359= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100975427; called by muse, mutect2, varscan2
- GOLM1 | c.981C>T p.D327= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs147755244; called by muse, mutect2, varscan2
- GPR50 | c.1785C>G p.T595= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV99506554; called by muse, mutect2, varscan2
- INF2 | c.1866G>A p.R622= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99384284; called by muse, varscan2
- JPT2 | c.297C>T p.V99= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99936243; called by muse, mutect2, varscan2
- KDR | c.2193C>T p.D731= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs138304068; called by muse, mutect2, varscan2
- KIRREL2 | c.2058C>T p.P686= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs1279352450, COSV52875803, COSV99384385; called by muse, mutect2, varscan2
- KRT37 | c.318G>A p.E106= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV56657856, COSV99845689; called by muse, mutect2, varscan2
- KRTAP15-1 | c.21T>A p.S7= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100481655; called by muse, mutect2, varscan2
- LDHB | c.555C>T p.S185= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100636431; called by muse, mutect2, varscan2
- LSG1 | c.1899G>A p.A633= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs1006521005, COSV99503514; called by muse, mutect2, varscan2
- MCAM | c.1596C>T p.L532= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as COSV99876956; called by muse, mutect2, varscan2
- MTMR9 | c.270G>A p.L90= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as rs1196103459, COSV99644556; called by muse, mutect2, varscan2
- MYO15A | c.5773C>T p.L1925= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV52760786, COSV52763461; called by muse, mutect2, varscan2
- NBAS | c.3564C>G p.L1188= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV55722546, COSV55740902; called by muse, mutect2, varscan2
- NLRP6 | c.1233G>A p.T411= | Silent (SNP) | VAF 45/194 reads (23%) | catalogued as COSV56460335; called by muse, mutect2, varscan2
- PCBP1 | c.957G>A p.V319= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100340120, COSV100340231; called by muse, mutect2, varscan2
- PHF24 | c.573C>T p.I191= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99646256; called by muse, mutect2, varscan2
- PICALM | c.96C>T p.H32= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100708208; called by muse, mutect2
- POLR1G | c.63G>A p.K21= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100338336; called by muse, mutect2, varscan2
- PRDM10 | c.3411G>A p.Q1137= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV100457007; called by muse, mutect2, varscan2
- ROBO2 | c.51G>A p.P17= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs79015247; called by muse, mutect2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- SPTY2D1 | c.1866C>T p.I622= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100311836; called by muse, varscan2
- SUPT7L | c.474C>G p.L158= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV61823108; called by muse, mutect2, varscan2
- TBC1D8 | c.3351C>T p.I1117= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV99961587; called by muse, mutect2, varscan2
- TCHH | c.1902G>A p.L634= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100915409; called by muse, mutect2, varscan2
- TMUB1 | c.321G>A p.L107= | Silent (SNP) | VAF 74/311 reads (24%) | catalogued as COSV99879955; called by muse, mutect2, varscan2
- TST | c.756C>T p.V252= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99968244; called by muse, mutect2, varscan2
- TTBK1 | c.1632C>A p.V544= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99445479; called by muse, mutect2, varscan2
- TTN | c.7341G>C p.V2447= (on ENST00000591111; = p.V2401= on NM_003319.4) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100627547, COSV100635301; called by muse, mutect2, varscan2
- TUBB4A | c.942C>T p.A314= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as rs199608353, COSV51164909, COSV99900065; called by muse, mutect2, varscan2
- UBFD1 | c.417G>A p.L139= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99563444; called by muse, mutect2, varscan2
- UNC13D | c.1626G>A p.T542= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs371924071; called by muse, mutect2, varscan2
- WDR62 | c.675C>T p.F225= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs1196668631, COSV99544161; called by muse, mutect2, varscan2
- XIRP1 | c.2016C>T p.G672= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV61140105; called by muse, mutect2, varscan2
- ZAN | c.996C>G p.V332= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100770277; called by muse, mutect2, varscan2
- ZMYND11 | c.432T>C p.V144= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100556892; called by muse, mutect2, varscan2
- ZNF490 | c.45C>T p.L15= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100267495, COSV100267517; called by muse, mutect2, varscan2
- ZNF580 | c.333C>T p.R111= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99553269; called by muse, mutect2
- AP000769.3 | chr11:65503191 G>C | 5'Flank (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- BMP1 | c.2108-605dup | Intron (INS) | VAF 38/214 reads (18%) | catalogued as rs759100606; called by mutect2, pindel, varscan2
- CABP1 | c.655-3623G>A | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as rs1488321914, COSV56459529; called by muse, mutect2, varscan2
- DST | c.4297-4422dup | Intron (INS) | VAF 40/193 reads (21%) | called by mutect2, pindel, varscan2
- FAM74A3 | n.262C>T | RNA (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- LCORL | c.*104G>C | 3'UTR (SNP) | VAF 31/106 reads (29%) | catalogued as COSV99266151; called by muse, mutect2, varscan2
- MIR519C | n.28G>A | RNA (SNP) | VAF 42/185 reads (23%) | called by muse, mutect2, varscan2
- MORF4 | n.549C>A | RNA (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- PRTFDC1 | c.339+28567G>C | Intron (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100197150; called by muse, mutect2
